Somatic mutation profile of tumor specimen TCGA-5V-A9RR-01A (aliquot TCGA-5V-A9RR-01A-11D-A423-09) from TCGA case TCGA-5V-A9RR, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 67.5 years (24,668 days).
Specimen TCGA-5V-A9RR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ddb2695-593f-4879-bc74-88b7710cecb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5V-A9RR-10A (Blood Derived Normal), aliquot TCGA-5V-A9RR-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb62a09c-3bf8-4c43-a59b-063d6f2e4750

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 107/478 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- ATP11C | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59574099; called by muse, mutect2
- MSH4 | c.1325A>G p.N442S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV54207957; called by muse, mutect2, varscan2
- OTOGL | c.6172A>G p.M2058V (on ENST00000547103; = p.M2049V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs1388452990; called by muse, mutect2, varscan2
- TSHZ1 | c.2596G>A p.D866N (on ENST00000580243 / NM_001308210.2; = p.D821N on NM_005786.6) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781613550; called by muse, mutect2, varscan2
- LTBP2 | c.799T>G p.S267A | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEL1L3 | c.2520G>A p.W840* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- UBLCP1 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1A | c.5538C>T p.P1846= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs754521399; called by muse, mutect2, varscan2
- COL17A1 | c.3300A>G p.L1100= | Silent (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2
- CSMD1 | c.663C>T p.S221= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs1183000468; called by muse, mutect2, varscan2
- FSCN3 | c.1407C>G p.A469= | Silent (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- NTRK2 | c.168G>A p.P56= | Silent (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- PRG4 | c.676T>C p.L226= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs768190713; called by muse, mutect2, varscan2
